Somatic mutation profile of tumor specimen TARGET-10-PANZUI-09A (aliquot TARGET-10-PANZUI-09A-01D) from TARGET case TARGET-10-PANZUI, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.6 years (3,136 days).
Specimen TARGET-10-PANZUI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7746c59-3404-4053-ace5-38b87ae3286c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANZUI-10A (Blood Derived Normal), aliquot TARGET-10-PANZUI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ebb32f71-1304-4a31-86fe-f9fef2015a31

The open-access MAF lists 19 somatic variants for this specimen: 11 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 6, Nonsense Mutation 2, Frame Shift Del 2, Intron 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP6 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs772160289, COSV61626940; called by muse, mutect2
- FAN1 | c.2264del p.E755Gfs*23 | Frame Shift Del (DEL) | VAF 38/88 reads (43%) | catalogued as rs756840415, COSV62951220; called by mutect2, pindel*, varscan2
- GALE | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs779150200; called by muse, mutect2, varscan2
- MYC | c.757G>A p.E253K (on ENST00000377970; = p.E268K on NM_002467.6) | Missense Mutation (SNP) | VAF 42/42 reads (100%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as COSV52368855; called by muse, mutect2, varscan2
- SETD2 | c.4775G>A p.R1592Q | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57439624, COSV57447701; called by muse, mutect2, varscan2
- SNX17 | c.925C>T p.R309* | Nonsense Mutation (SNP) | VAF 56/101 reads (55%) | catalogued as rs777906560; called by muse, mutect2, varscan2
- DIP2C | c.4155T>A p.Y1385* | Nonsense Mutation (SNP) | VAF 31/70 reads (44%) | called by muse, mutect2, varscan2
- IGKV2D-30 | chr2:89937678 CTCCCACAGTGGTA>TCCTTAGGG | Missense Mutation (DEL) | VAF 25/33 reads (76%) | called by pindel, varscan2*
- IMPG1 | c.848T>A p.I283N | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KMT2D | c.4132-2A>G p.X1378_splice | Splice Site (SNP) | VAF 40/88 reads (45%) | called by muse, mutect2, varscan2
- WDR17 | c.1030del p.S344Afs*9 | Frame Shift Del (DEL) | VAF 31/137 reads (23%) | called by mutect2, pindel, varscan2
- AVEN | c.753C>T p.C251= | Silent (SNP) | VAF 9/91 reads (10%) | catalogued as rs370527932; called by muse, mutect2
- DPYSL3 | c.72C>T p.G24= | Silent (SNP) | VAF 26/50 reads (52%) | called by muse, mutect2, varscan2
- KCNB2 | c.1449C>T p.D483= | Silent (SNP) | VAF 42/75 reads (56%) | catalogued as rs555669570, COSV73051774; called by muse, mutect2, varscan2
- LMAN1 | c.1104G>A p.E368= | Silent (SNP) | VAF 56/134 reads (42%) | called by muse, mutect2, varscan2
- ODF1 | c.87C>T p.D29= | Silent (SNP) | VAF 110/113 reads (97%) | catalogued as rs369351331; called by muse, mutect2, varscan2
- ZNF474 | c.192G>T p.G64= | Silent (SNP) | VAF 53/123 reads (43%) | catalogued as COSV56946643; called by muse, mutect2, varscan2
- COLCA2 | c.-96A>G | 5'UTR (SNP) | VAF 38/62 reads (61%) | called by muse, mutect2, varscan2
- MLLT10 | c.240+17911C>T | Intron (SNP) | VAF 49/101 reads (49%) | catalogued as rs1401136355; called by muse, mutect2, varscan2
